TARGET case TARGET-40-0A4I9I — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/8a3df64f-8fa6-490b-9f90-5b63f74f8f4f

Demographics
Sex at birth: male; Vital status: Dead; Days to death: 2,014 days (5.5 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; Tissue or organ of origin: Bone, NOS; Site of resection or biopsy: Long bones of lower limb and associated joints; Age at diagnosis: 89.0 years (32,518 days); Days to last follow up: 2,014 days (5.5 years).

Biospecimens (2 samples)
- Sample TARGET-40-0A4I9I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4I9I-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
